Somatic mutation profile of tumor specimen 0DJILP from CCDI case PBBWUZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.1 years (8,441 days).
Specimen 0DJILP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc72232f-b2f8-4c45-8133-ba306a2925ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73d48977-eae1-4b4c-8bbd-b63e15d9d8e0

The open-access MAF lists 41 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Intron 6, 3'UTR 3, Frame Shift Ins 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.261); catalogued as rs776828648, COSV52005296; called by muse, mutect2, varscan2
- ADGRL3 | c.1824G>T p.W608C (on ENST00000506720 / NM_001322402.2; = p.W540C on NM_015236.6) | Missense Mutation (SNP) | VAF 415/891 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778089871, COSV72229323, COSV72230689; called by muse, mutect2, varscan2
- APC | c.1490dup p.R498Kfs*39 | Frame Shift Ins (INS) | VAF 468/1371 reads (34%) | catalogued as CI040195; called by mutect2, varscan2
- CDC42BPB | c.3274C>T p.R1092* | Nonsense Mutation (SNP) | VAF 199/428 reads (46%) | catalogued as rs1260927406, COSV63474296; called by muse, mutect2, varscan2
- CEL | c.635C>T p.T212M (on ENST00000673714; = p.T209M on NM_001807.6) | Missense Mutation (SNP) | VAF 191/457 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747153235; called by muse, mutect2, varscan2
- CLOCK | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 244/608 reads (40%) | catalogued as COSV59400616; called by muse, mutect2, varscan2
- DDX3X | c.1048C>T p.R350W (on ENST00000399959; = p.R351W on NM_001356.5) | Missense Mutation (SNP) | VAF 66/464 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67864267; called by muse, mutect2, varscan2
- GABRA2 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 374/933 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734874, COSV62915759; called by muse, mutect2, varscan2
- ITGB4 | c.2721A>T p.E907D | Missense Mutation (SNP) | VAF 51/480 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV99564636; called by muse, mutect2, varscan2
- NTN4 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 301/641 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs200728319; called by muse, mutect2, varscan2
- OVOL2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 202/492 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751236489, COSV99602317; called by mutect2, varscan2
- SMARCA4 | c.3703G>T p.D1235Y | Missense Mutation (SNP) | VAF 242/598 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60785997; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 46/594 reads (8%) | PolyPhen probably damaging (1); catalogued as rs150742627; called by muse, mutect2
- ZNF226 | c.1094G>T p.C365F | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767706363; called by muse, mutect2
- ACAP3 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 119/282 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAMK2A | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 34/654 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); called by muse, mutect2
- ITIH3 | c.1880C>G p.P627R | Missense Mutation (SNP) | VAF 48/698 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2
- MTA1 | c.694T>A p.S232T | Missense Mutation (SNP) | VAF 140/407 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MYMX | c.115C>A p.R39S | Missense Mutation (SNP) | VAF 40/788 reads (5%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2
- PLXNB2 | c.1955A>G p.N652S | Missense Mutation (SNP) | VAF 31/540 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- PLXNB3 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 227/233 reads (97%) | SIFT tolerated (0.24); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RTN4 | c.2337G>C p.M779I | Missense Mutation (SNP) | VAF 542/1117 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SP5 | c.1009_1015dup p.R339Lfs*45 | Frame Shift Ins (INS) | VAF 95/366 reads (26%) | called by mutect2, varscan2
- CPXM2 | c.144G>A p.A48= | Silent (SNP) | VAF 29/282 reads (10%) | called by muse, mutect2, varscan2
- GLI1 | c.882A>G p.R294= | Silent (SNP) | VAF 268/698 reads (38%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.495A>C p.G165= | Silent (SNP) | VAF 60/889 reads (7%) | called by muse, mutect2
- ITGB2 | c.474C>T p.N158= | Silent (SNP) | VAF 58/680 reads (9%) | catalogued as rs753440204, COSV100186137, COSV56608645; called by muse, mutect2
- LDLRAD1 | c.582C>T p.S194= | Silent (SNP) | VAF 165/534 reads (31%) | catalogued as rs929359424; called by muse, mutect2, varscan2
- OR6C76 | c.834C>T p.V278= | Silent (SNP) | VAF 453/1033 reads (44%) | catalogued as rs199501701; called by muse, mutect2, varscan2
- SLC24A3 | c.87C>T p.F29= | Silent (SNP) | VAF 245/540 reads (45%) | called by muse, mutect2, varscan2
- SLC4A4 | c.216T>C p.N72= | Silent (SNP) | VAF 52/1084 reads (5%) | catalogued as rs1022639313; called by muse, mutect2
- WDR19 | c.2673C>T p.H891= | Silent (SNP) | VAF 269/588 reads (46%) | catalogued as rs753954843, COSV56466922; called by muse, mutect2, varscan2
- CARM1 | c.*55C>T | 3'UTR (SNP) | VAF 84/206 reads (41%) | catalogued as rs531247584; called by muse, mutect2, varscan2
- GALNT16 | c.177+71C>G | Intron (SNP) | VAF 64/164 reads (39%) | called by muse, mutect2, varscan2
- KDM8 | c.666-27C>A | Intron (SNP) | VAF 78/172 reads (45%) | called by muse, mutect2, varscan2
- NR3C1 | c.*2455C>T | 3'UTR (SNP) | VAF 52/953 reads (5%) | catalogued as rs552256509; called by muse, mutect2
- PLD2 | c.1921-41G>T | Intron (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- RPL10 | c.*165C>T | 3'UTR (SNP) | VAF 178/184 reads (97%) | catalogued as rs192756674; called by muse, mutect2, varscan2
- TMCO4 | c.1265-25G>C | Intron (SNP) | VAF 96/189 reads (51%) | called by muse, mutect2, varscan2
- TNRC6A | c.4122+42dup | Intron (INS) | VAF 68/158 reads (43%) | catalogued as rs773383340; called by mutect2, varscan2
- ZMYM2 | c.3453+746G>C | Intron (SNP) | VAF 231/530 reads (44%) | called by muse, mutect2, varscan2
